Somatic mutation profile of tumor specimen TCGA-BP-5009-01A (aliquot TCGA-BP-5009-01A-01D-1462-08) from TCGA case TCGA-BP-5009, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 52.2 years (19,052 days).
Specimen TCGA-BP-5009-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6bb027d1-04c4-4533-8124-f2e0720e494c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5009-11A (Solid Tissue Normal), aliquot TCGA-BP-5009-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c07d091b-aba5-40bc-903e-d89feb042da9

The open-access MAF lists 51 somatic variants for this specimen: 42 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 8, Frame Shift Del 4, Splice Site 2, In Frame Del 2, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT3 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 13/65 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397514606, COSV55605820, COSV55624598; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VHL | c.232A>T p.N78Y | Missense Mutation (SNP) | VAF 4/8 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs869025621, CM130353, CM130970, CM941365, COSV56545109, COSV56549825, COSV56558459; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.1914C>G p.D638E | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as COSV100588532, COSV59392309; called by muse, mutect2
- ADD1 | c.1408A>G p.T470A | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as COSV53274216; called by muse, mutect2, varscan2
- AGA | c.982T>A p.F328I | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.812); catalogued as COSV52807640; called by muse, mutect2, varscan2
- C11orf24 | c.530C>T p.T177I | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.11); catalogued as rs868651930, COSV58506539; called by muse, mutect2, varscan2
- CACNA1S | c.3071T>A p.I1024K | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62943494; called by muse, mutect2, varscan2
- CALCOCO2 | c.655_657del p.M219del | In Frame Del (DEL) | VAF 23/73 reads (32%) | catalogued as rs1567755785; called by mutect2, pindel, varscan2
- CDC42BPA | c.3923T>C p.L1308P (on ENST00000334218 / NM_001366019.2; = p.L1295P on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV62021351; called by muse, mutect2
- CHM | c.789T>G p.I263M | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV63304459; called by muse, mutect2, varscan2
- CSK | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54975900; called by muse, mutect2, varscan2
- DENND2D | c.1066G>C p.D356H | Missense Mutation (SNP) | VAF 13/451 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.336); catalogued as COSV62960024; called by muse, mutect2
- DNAH11 | c.4126G>A p.V1376I | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs531283952, COSV60938522, COSV60977719; called by muse, mutect2, varscan2
- DNAH2 | c.5100C>A p.N1700K | Missense Mutation (SNP) | VAF 156/631 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as COSV66726936; called by muse, mutect2, varscan2
- EML2 | c.452A>G p.H151R | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.609); catalogued as COSV55598444, COSV55603835; called by muse, mutect2, varscan2
- FAT3 | c.6866A>G p.Q2289R | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.076); catalogued as rs765720273, COSV53171943; called by muse, mutect2, varscan2
- FN1 | c.5041G>C p.D1681H | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); catalogued as COSV60563915; called by muse, mutect2, varscan2
- GALNT14 | c.888del p.K297Nfs*27 | Frame Shift Del (DEL) | VAF 49/205 reads (24%) | catalogued as COSV61104298; called by mutect2, pindel, varscan2
- MMP20 | c.492A>C p.E164D | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV52778113; called by muse, mutect2, varscan2
- NAA40 | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 9/239 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.364); catalogued as rs1192953616, COSV58161977; called by muse, mutect2
- NAV1 | c.1160C>A p.S387Y | Missense Mutation (SNP) | VAF 56/207 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV55226105; called by muse, mutect2, varscan2
- NCAPG2 | c.1109T>G p.M370R | Missense Mutation (SNP) | VAF 95/250 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV51991635; called by muse, mutect2, varscan2
- OR52B4 | c.902T>C p.I301T | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1361261985, COSV68769476; called by muse, mutect2, varscan2
- PIWIL4 | c.187G>C p.G63R | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as COSV54412444; called by muse, mutect2, varscan2
- PROS1 | c.235-1G>T p.X79_splice | Splice Site (SNP) | VAF 6/54 reads (11%) | catalogued as CS163626, COSV62399662; called by muse, mutect2, varscan2
- PRSS36 | c.77T>C p.L26P | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV51639655; called by muse, mutect2
- PTPN13 | c.4875G>C p.E1625D (on ENST00000411767 / NM_080683.3; = p.E1606D on NM_006264.3) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV57417099; called by muse, varscan2
- RAN | c.88C>T p.H30Y | Missense Mutation (SNP) | VAF 21/251 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as COSV54563352; called by muse, mutect2
- RPS3 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 47/215 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as rs528039603, COSV53705469; called by muse, mutect2, varscan2
- SLC17A6 | c.1195C>G p.L399V | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as COSV54138711, COSV54141154; called by muse, mutect2, varscan2
- SLC4A1 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.685); catalogued as rs372860708, COSV52258917; called by muse, mutect2, varscan2
- SLIT2 | c.2446A>C p.I816L | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.951); catalogued as COSV56594663; called by muse, mutect2, varscan2
- TERT | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.377); catalogued as COSV57239274; called by muse, mutect2
- THSD1 | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 70/245 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as COSV51627765; called by muse, varscan2
- TPO | c.2118G>A p.M706I | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV61111003; called by muse, mutect2, varscan2
- WDR81 | c.3769T>C p.Y1257H (on ENST00000409644 / NM_001163809.2; = p.Y206H on NM_152348.4) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58488271; called by muse, mutect2, varscan2
- ANK2 | c.7606del p.L2536Ffs*22 | Frame Shift Del (DEL) | VAF 45/201 reads (22%) | called by mutect2, pindel, varscan2
- ATM | c.6195del p.Q2066Rfs*16 | Frame Shift Del (DEL) | VAF 21/86 reads (24%) | called by mutect2, pindel, varscan2
- DLD | c.361_366del p.D121_K122del | In Frame Del (DEL) | VAF 15/87 reads (17%) | called by mutect2, pindel, varscan2
- PBRM1 | c.876_885del p.M292Ifs*5 | Frame Shift Del (DEL) | VAF 5/34 reads (15%) | called by mutect2, pindel
- TMBIM1 | c.514-2dup p.X172_splice | Splice Site (INS) | VAF 21/92 reads (23%) | called by mutect2, pindel, varscan2
- ZNF564 | c.1278_1279dup p.G427Vfs*15 | Frame Shift Ins (INS) | VAF 75/386 reads (19%) | called by mutect2, pindel, varscan2
- HIVEP2 | c.1737A>T p.P579= | Silent (SNP) | VAF 31/147 reads (21%) | catalogued as COSV50059071; called by muse, mutect2, varscan2
- JUP | c.177C>T p.T59= | Silent (SNP) | VAF 12/109 reads (11%) | catalogued as COSV60279697; called by muse, mutect2, varscan2
- KCNJ8 | c.1149C>A p.R383= | Silent (SNP) | VAF 61/366 reads (17%) | catalogued as COSV53718226; called by muse, mutect2, varscan2
- LAMB3 | c.1632G>A p.P544= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs753960912, COSV100620549, COSV61919620; called by muse, mutect2, varscan2
- PEG3 | c.2481A>G p.G827= | Silent (SNP) | VAF 14/162 reads (9%) | catalogued as COSV55647005; called by muse, mutect2
- PKD2L2 | c.396T>G p.R132= | Silent (SNP) | VAF 35/231 reads (15%) | catalogued as COSV51801562; called by muse, mutect2, varscan2
- SDC1 | c.567G>A p.E189= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as COSV54341566; called by muse, mutect2, varscan2
- TUBB | c.1287C>A p.T429= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as COSV58358332; called by muse, mutect2, varscan2
- SLC30A2 | c.271+631G>C | Intron (SNP) | VAF 11/33 reads (33%) | catalogued as COSV65333365; called by muse, mutect2, varscan2
